Gene-level copy-number profile of tumor specimen C3L-02809-04 from CPTAC case C3L-02809, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 84.0 years (30,685 days).
Specimen C3L-02809-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5ad2de7f-eb4b-431c-a970-a6278ab7c546.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02809-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/8e9b476f-5ec1-4e42-b917-07da6a709de4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 355; copy number 1: 12,449; copy number 2: 40,176; copy number 3: 5,779; copy number 4: 7; copy number 5: 6; copy number 6: 93; copy number 7: 6; copy number 8: 1; copy number 10: 3; copy number 13: 7; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,029,594, 10 genes (within-gene range 0–1): KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 117 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,784,324–39,417,378, 73 genes, copy number 6–7 (broad region; genes not listed).
- chr8:39,522,976–39,580,134, 1 gene, copy number 6: AC123767.1.
- chr8:39,903,775–39,995,248, 1 gene, copy number 7 (within-gene range 3–7): AC007991.3.
- chr8:39,934,614–40,016,391, 2 genes, copy number 7: IDO2, AC007991.1.
- chr18:21,981,121–23,026,488, 22 genes, copy number 6 (within-gene range 3–6): LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr18:23,453,287–23,586,506, 5 genes, copy number 5 (within-gene range 1–5): RIOK3, Y_RNA, AC026634.1, RMC1, NPC1.
- chr20:21,947,647–21,970,783, 1 gene, copy number 8: AL109807.1.
- chr20:22,220,554–22,886,068, 12 genes, copy number 5–18: AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4.

Autosomal genes at a single copy (total copy number 1): 9,970. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
